Somatic mutation profile of tumor specimen BA2332D (aliquot aq-BA2332D) from BEATAML1.0 case 2331, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,952 days).
Specimen BA2332D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01355f11-a81e-499a-a4a0-c791fb1d736a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2537D (Solid Tissue Normal), aliquot aq-BA2537D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1df0f46-5443-45c9-9369-fc59468499de

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL20RA | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs377051637, COSV100359969; called by muse, mutect2, varscan2
- THEMIS | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as COSV64069646; called by muse, mutect2, varscan2
- ZNRD2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.666); catalogued as COSV57079300; called by muse, mutect2
- MYT1L | c.3224A>G p.E1075G | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SNX20 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.425); called by muse, mutect2
- ZNF239 | c.631_634del p.Q211Vfs*115 | Frame Shift Del (DEL) | VAF 30/215 reads (14%) | called by mutect2, pindel, varscan2
- CSPG4 | c.477G>T p.L159= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100413299; called by muse, mutect2
- UMOD | c.654G>T p.V218= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- IL18BP | c.*34G>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99474491; called by muse, mutect2
